Gene-level copy-number profile of tumor specimen TCGA-91-A4BC-01A from TCGA case TCGA-91-A4BC, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.0 years (21,565 days).
Specimen TCGA-91-A4BC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.35862eb5-aaf2-4b03-9ebe-7f622260dab0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-91-A4BC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/05339e5c-537a-4e27-bff0-f3d3184b3b67

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 4,216; copy number 2: 38,112; copy number 3: 11,787; copy number 4: 4,586; copy number 5: 539; copy number 6: 486; copy number 7: 78.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-91-A4BC-01A-11D-A24C-01): tumor purity 0.22, ploidy 2.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,103 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–153,391,073, 422 genes, copy number 5 (broad region; genes not listed).
- chr8:46,028,804–83,408,900, 564 genes, copy number 6–7 (broad region; genes not listed).
- chr14:26,443,090–34,875,647, 117 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,216. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
